Somatic mutation profile of tumor specimen TCGA-AB-2841-03B (aliquot TCGA-AB-2841-03B-01W-0728-08) from TCGA case TCGA-AB-2841, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute promyelocytic leukaemia, t(15;17)(q22;q11-12); Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.5 years (18,809 days).
Specimen TCGA-AB-2841-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b2c56c1-b12b-4d32-bad4-8aba03b0166a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2841-11B (Solid Tissue Normal), aliquot TCGA-AB-2841-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/564c1c84-57f6-4eda-a805-f8f542fee621

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf56 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV67756570; called by muse, mutect2, varscan2
- ZNF662 | c.259G>T p.V87L | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.191); catalogued as COSV100066155; called by muse, mutect2
- KRT34 | c.1029G>A p.T343= | Silent (SNP) | VAF 52/165 reads (32%) | catalogued as rs148874673; called by muse, mutect2
- KRT79 | c.1017C>T p.T339= | Silent (SNP) | VAF 226/526 reads (43%) | catalogued as rs748091012, COSV57942693; called by muse, mutect2, varscan2
